Somatic mutation profile of tumor specimen TCGA-KK-A8I5-01A (aliquot TCGA-KK-A8I5-01A-11D-A364-08) from TCGA case TCGA-KK-A8I5, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.7 years (20,337 days).
Specimen TCGA-KK-A8I5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0eaa3a5b-268a-4234-ae6e-408813a10bdf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8I5-11A (Solid Tissue Normal), aliquot TCGA-KK-A8I5-11A-11D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05f0affb-6288-4c71-b2eb-89dbd4d2395f

The open-access MAF lists 40 somatic variants for this specimen: 28 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 25, Silent 12, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF17 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs771690518, COSV99737208; called by muse, mutect2, varscan2
- BPIFB4 | c.1193G>T p.W398L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1437848798, COSV100971689; called by muse, mutect2, varscan2
- CNTNAP5 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV101444387, COSV70485478; called by muse, mutect2, varscan2
- CSRNP1 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs746438028, COSV99827212; called by muse, mutect2, varscan2
- CYP2B6 | c.287C>A p.S96Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100137865; called by muse, mutect2, varscan2
- DNAH3 | c.4225G>A p.D1409N | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764435816, COSV54501536, COSV54543988; called by muse, mutect2, varscan2
- FCGBP | c.12418C>T p.R4140C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as rs145000879; called by muse, mutect2, varscan2
- FGB | c.970C>A p.L324I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1280158281, COSV100122577; called by muse, mutect2, varscan2
- GIGYF2 | c.2071A>G p.I691V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.028); catalogued as rs1335756295, COSV101004671; called by muse, mutect2, varscan2
- GRIK3 | c.397A>C p.I133L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.04); catalogued as COSV100902487; called by muse, mutect2, varscan2
- GRM8 | c.681T>A p.Y227* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100286895; called by muse, mutect2, varscan2
- ICAM2 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs773666503, COSV56743916; called by muse, mutect2, varscan2
- ISOC2 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as rs778151043, COSV99321378; called by muse, mutect2, varscan2
- JAKMIP1 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs1313972918, COSV51539800; called by muse, mutect2, varscan2
- KCNN1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs774107476; called by muse, mutect2, varscan2
- NRDC | c.1711G>A p.V571M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV100704006; called by muse, mutect2, varscan2
- PCSK2 | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as COSV99361073; called by muse, mutect2, varscan2
- PRSS48 | c.934T>G p.C312G | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV101490193; called by muse, mutect2, varscan2
- SLC16A7 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV53892015, COSV99676974; called by muse, mutect2, varscan2
- SLC8A1 | c.35C>G p.T12S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.01); catalogued as rs142661656, COSV100247701; called by muse, mutect2, varscan2
- TCERG1 | c.3241C>G p.R1081G | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57035703, COSV99695412; called by muse, mutect2, varscan2
- TIGD3 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1434878304, COSV99362050; called by muse, mutect2, varscan2
- TM7SF3 | c.760T>C p.Y254H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100545052; called by muse, mutect2, varscan2
- TMEM31 | c.289T>A p.F97I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV100129139; called by muse, mutect2, varscan2
- XIRP1 | c.5003C>T p.S1668F | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs747906215, COSV100454073; called by muse, mutect2, varscan2
- YPEL4 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs1460332021, COSV55518874; called by muse, mutect2, varscan2
- ANKRD13A | c.1770del p.K590Nfs*7 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, pindel, varscan2
- MYOF | c.5735del p.P1912Lfs*12 | Frame Shift Del (DEL) | VAF 63/135 reads (47%) | called by mutect2, pindel, varscan2
- CIITA | c.1059C>T p.P353= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs769294144, COSV60857897; called by muse, mutect2, varscan2
- EDIL3 | c.1002G>A p.Q334= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV99679788; called by muse, mutect2, varscan2
- GJC1 | c.816G>C p.P272= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV100395262; called by muse, mutect2, varscan2
- IGHV1-69 | c.348G>A p.A116= | Silent (SNP) | VAF 28/172 reads (16%) | catalogued as rs782645516; called by muse, mutect2, varscan2
- NUP214 | c.5589C>T p.G1863= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as COSV100845422; called by muse, mutect2
- PCDHGA1 | c.2190C>T p.G730= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV65294725; called by muse, mutect2, varscan2
- RGS9BP | c.123A>G p.Q41= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100043242; called by muse, mutect2, varscan2
- SHANK1 | c.381C>T p.R127= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs377430056; called by muse, mutect2, varscan2
- SOX1 | c.339G>A p.K113= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100447186, COSV58378478; called by muse, mutect2
- UBXN4 | c.627G>A p.R209= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99739768; called by muse, mutect2, varscan2
- USP42 | c.1236C>T p.S412= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs772997740, COSV100085031; called by muse, mutect2, varscan2
- ZAN | c.5577C>A p.T1859= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100769690; called by muse, mutect2, varscan2
